Surgical pathology report (de-identified scan), TCGA case TCGA-06-0409, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0409-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

MRI

Birth Date:

Male Room/Bed:

PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX: M

RECEIVE DATE:

PHYSICIAN:

COPY TO:

UPDATED REPORT

- SEE ADDENDUM DIAGNOSIS AND /
REPORTUUID: C86D5812-C171-47C7-A648-18680309D777

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, SITE NOT SPECIFIED, EXCISIONAL BIOPSIES: GLIOBLAS
MULTIFORME.
- B. BRAIN, SITE NOT SPECIFIED, EXCISIONAL BIOPSY: GLIOBLASTOMA
MULTIFORME.

SEE MICROSCOPIC AND COMMENT

ADDENDUM DIAGNOSIS:

BRAIN, IMMUNOHISTOCHEMISTRY: MIB-1 LABELLING INDEX 11%.

Operation/Specimen: Brain.

Clinical History and Pre-Op Dx: year old man with past history of
glioblastoma multiforme. Recurrent tumor?

GROSS PATHOLOGY:

- A. Received fresh, two fragments, 1.3 x 1 x 0.5 cm in aggregate.
Semi-firm, tannish-gray, glistening. In total #1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, biopsies: Malignant glioma.

B.

SPECIMEN: Tumor.

FIXATIVE: None.

GENERAL: Two, each 0.6 cm. in greatest dimensions soft, red-tan
fragments.

SECTIONS: X1 - all.

MICROSCOPIC: A. Portions of a moderately cellular neoplastic glial
proliferation. The neoplastic cells are elongated with nuclear
features of anaplasia, and are disposed in a fibrillary background.
There are frequent individual cell necrosis and mitotic figures.
Microvascular cellular proliferation is present throughout, and focally

Cont'd.....

some vessels have thick hyalinized walls. There is one small focal
area of tumor necrosis with pseudopalisading. A rare neuron is

[page 2 of 4]
Patient Name:

MRN

Birth Date:

Sex

Age

Room/Bed:

present, and interpreted as native.

Portions of a neoplasm similar to that one described in part A. In there there are several areas of coagulation necrosis with pseudopalisading.

COMMENT: The specimens contain a viable and actively proliferating glioblastoma multiforme. The hyalinizing change observed in some vessels may be associated with post radiation effect.

ADDENDUM REPORT

IMMUNOHISTOCHEMISTRY: An immunoperoxidase method for MIB-1 was performed on block #2. A labelling index of 11% was determined in the more cellular areas.

TISSUE COMMITTEE CODE:

BILLING CODES:

[page 3 of 4]
Patient Name:

MRN:

Birth Date:

Sex: Male Room/Bed:

PATIENT NAME:

HIST. NO.:

AGE/SEX:

M

ORDERING PHYSICIAN:

PATH. NO:

NAME:

MED. REC. NO:

RECEIVE DATE:

PHYSICIAN:

PATHOLOGICAL DIAGNOSIS:

BRAIN, RIGHT FRONTOPIRIETAL AREA, EXCISIONAL BIOPSY: GLIOBLASTOMA
MULTIFORME. SEE MICROSCOPIC DESCRIPTION AND COMMENT.

Operation/Specimen: Right frontoparietal tumor.

Clinical History and Pre-Op Dx: year old man with a ring-shaped
lesion in the right cerebral hemisphere, frontal. CT in with no
lesion.

GROSS PATHOLOGY: Specimen 1, received in fresh state and labeled with
the patient's name for frozen section, consists of two small fragments
of tan, hemorrhagic, glassy friable soft tissue measuring 0.2 and 0.15
cm. across respectively. Smears and frozen sections are obtained.
Tissue utilized for frozen sections submitted in cassette 1, remaining
tissue submitted totally in cassette 2. Frozen section diagnosis:
Brain, right frontoparietal, biopsy: high grade glioma.

Specimen 2, right frontoparietal, received in fresh state for permanent
sections and labeled with the patient's name, consists of a somewhat
rounded and 2.8 cm. in largest diameter mass of semifirm tissue. The
external surface of the mass is irregular, focally hemorrhagic and
about half of its surface appears brown and necrotic. On serial
section, the mass exhibits a central area of brown soft necrotic tissue
surrounded by a more homogeneous yellowish area, and a more peripheral
rim of grayish-white, glistening and somewhat granular homogeneous
tissue. About 2/3 of the specimen are submitted for paraffin embedding
in cassettes 3 thru 5.

MICROSCOPIC: All the microscopic slides contain portions of a
neoplastic astrocytic proliferation with a marked degree of nuclear and
cellular anaplasia, focally high mitotic rate, very prominent
endothelial/vascular proliferation, and extensive areas of necrosis.
The neoplasm is diffusely infiltrating the cerebral cortex and focally
extends into the leptomeningeal space.

COMMENT: The lesion is a very characteristic glioblastoma multiforme
with a central area of necrosis surrounded by a ring-shaped portion of
neoplastic tissue with prominent endothelial vascular proliferation.
The tumor is focally growing into the leptomeningeal space. An MIB-1
immunoperoxidase stain for proliferation indexing is requested and
further report will follow.

BILLING CODES:

ADDENDUM

[page 4 of 4]
Patient Name:

MRN: :

Birth Date:

Sex: Male Room/Bed:

Immunoperoxidase stain for the Ki-67 antigen with the MIB-1 antibody
w performed on block no. 3.

The proliferation index in this malignant glioma is 18-20%.

COMMENT: This high mitotic index correlates well with the H&E highly
anaplastic appearance of this glioblastoma multiforme.

Source: NCI Genomic Data Commons file 7935c626-9c35-4244-b4e6-484a0b4a8a31 (TCGA-06-0409.C86D5812-C171-47C7-A648-1B6B0309D777.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).